Surgical pathology report (de-identified scan), TCGA case TCGA-AA-A02O, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-A02O-01A (Primary Tumor).

TCGA #	Internal Sample ID
--------	--------------------

Diagnosis:

This is an invasive, moderately differentiated adenocarcinoma of the colon, G 2,
with permeation of all wall layers, p T 3,
with lymphatic vessel invasion, L 1,
otherwise free lymph nodes (0 of 18).

Tumor classification:

ICD-O-DA M 8140/3

G 2,

p T 3, p N 0, L 2.

The resection margins were free.

ICD-O-3

adenocarcinoma, NOS 8140/3

Site: transverse colon C18.4 AW 9/30/11

4pAA Discrepancy		

Signature: *[Handwritten Signature]*

Source: NCI Genomic Data Commons file d8ed9e75-d33b-42c0-9ae1-eae7bb42e739 (TCGA-AA-A02O.AEB46243-5146-48F3-A59B-A9455C72F0F5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).